HCMI case HCM-BROD-0701-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/76190b91-c744-4fc5-8e4d-eba10785d98b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1944.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 74.1 years (27,073 days); AJCC staging edition: 8th; AJCC clinical stage: Stage III; AJCC pathologic T: T4b; AJCC pathologic N: N3b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 323 days; Days to treatment end: 449 days (1.2 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Chemotherapy, for residual disease; adjuvant Hormone Therapy, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/6; ICD-10 code: C77.4; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 74.9 years (27,346 days); Days to diagnosis: 273 days; Satellite nodule present: Absent.
   Pathology details: Breslow thickness category: >4.0 mm; Lymph nodes positive: 7; Lymph nodes tested: 25; Lymphatic invasion present: Yes; Perineural invasion present: No; Vascular invasion present: Yes.

Follow-up (2 entries)
- Days to follow up: 472 days (1.3 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 342.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 89 kg; Height: 182 cm; BMI: 26.

Exposures
- Tobacco smoking status: Current Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0701-C43-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0701-C43-06B-01-S1-HE: Section location: Top; Percent tumor cells: 81; Percent tumor nuclei: 85; Percent normal cells: 14; Percent necrosis: 3; Percent stromal cells: 2; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 8; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0701-C43-06B-01-S2-HE: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 78; Percent normal cells: 21; Percent necrosis: 1; Percent stromal cells: 3; Percent lymphocyte infiltration: 6; Percent monocyte infiltration: 11; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0701-C43-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0701-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 9.
